Somatic mutation profile of tumor specimen MMRF_2543_1_BM_CD138pos (aliquot MMRF_2543_1_BM_CD138pos_T1_KHS5U_L12916) from MMRF case MMRF_2543, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.8 years (25,125 days).
Specimen MMRF_2543_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff4dbc0f-df1c-48cb-bb84-cacb69339953.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2543_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2543_1_PB_WBC_C3_KHS5U_L12915; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b32510b6-fbe6-4919-a95c-d2122ad30f10

The open-access MAF lists 75 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 21, Silent 10, Intron 9, 5'UTR 2, 5'Flank 2, Nonsense Mutation 1, Splice Region 1, Frame Shift Ins 1, Splice Site 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INSR | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs121913150, CM920379, COSV100253840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 32/135 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AASS | c.767-1G>T p.X256_splice | Splice Site (SNP) | VAF 25/176 reads (14%) | catalogued as COSV100741666; called by muse, mutect2, varscan2
- ADGRL2 | c.2618G>A p.R873H (on ENST00000370717 / NM_001366005.1; = p.R860H on NM_012302.4) | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs576674053, CM161445, COSV54651236; called by muse, mutect2, varscan2
- C1orf100 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 171/737 reads (23%) | catalogued as rs200838303; called by muse, mutect2, varscan2
- CENPE | c.4176G>A p.M1392I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as rs1409554865; called by muse, mutect2
- ERP27 | c.782A>T p.N261I | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV99844320; called by muse, mutect2
- FAT4 | c.13686C>A p.D4562E | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100627160; called by muse, mutect2, varscan2
- KCNJ2 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199473657, CM066889, COSV54663257; ClinVar: not provided; called by muse, mutect2, varscan2
- MAX | c.137T>G p.L46W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52415235, COSV99408404; called by muse, mutect2, varscan2
- PPP4R3B | c.1157T>C p.I386T | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1226876814; called by muse, mutect2
- RITA1 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767313400; called by muse, varscan2
- SLC5A6 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs1258393679; called by muse, mutect2, varscan2
- C14orf39 | c.771T>G p.I257M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CD36 | c.403T>G p.F135V | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CDK13 | c.3362A>G p.E1121G | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CDKL3 | c.648dup p.V217Sfs*40 | Frame Shift Ins (INS) | VAF 56/303 reads (18%) | called by mutect2, pindel
- COL23A1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2
- CXXC4 | c.1082A>T p.E361V | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- DNAJB12 | c.470A>G p.D157G (on ENST00000338820; = p.D123G on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- MAGI1 | c.1043-5A>G | Splice Region (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- METTL5 | c.146A>T p.D49V | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYO5C | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- NETO1 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRXN3 | c.1913C>T p.S638F (on ENST00000335750 / NM_001330195.2; = p.S265F on NM_004796.6) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PMM1 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- S100A7 | c.53A>T p.H18L | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UBXN7 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZC3H4 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CNGB3 | c.1998C>T p.F666= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- IGLV7-43 | c.286C>T p.L96= | Silent (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
- MYO1H | c.378G>T p.G126= | Silent (SNP) | VAF 37/194 reads (19%) | called by muse, mutect2, varscan2
- RPSA | c.420T>A p.V140= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- SULF2 | c.6C>T p.G2= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as rs554725545, COSV100737226; called by muse, mutect2
- TAF7L | c.780C>T p.D260= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs368931640, COSV100229676; called by muse, mutect2, varscan2
- TMEM215 | c.291C>A p.T97= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as rs1313866478, COSV61363129; called by muse, mutect2
- UNC13A | c.3684G>A p.V1228= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- VPS41 | c.1800G>A p.K600= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs1262499859; called by muse, mutect2, varscan2
- WDR36 | c.117T>A p.G39= | Silent (SNP) | VAF 35/134 reads (26%) | called by muse, mutect2, varscan2
- ACAP3 | c.*880G>T | 3'UTR (SNP) | VAF 7/154 reads (5%) | called by muse, mutect2
- AP000769.5 | chr11:65499242 T>C | 5'Flank (SNP) | VAF 8/51 reads (16%) | catalogued as rs1565674310; called by muse, mutect2, varscan2
- ARTN | c.*6C>T | 3'UTR (SNP) | VAF 9/95 reads (9%) | catalogued as rs745323674, COSV100964364; called by muse, mutect2, varscan2
- CSMD3 | c.*1329T>G | 3'UTR (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- CST9 | c.-41G>T | 5'UTR (SNP) | VAF 8/81 reads (10%) | catalogued as rs1394990922; called by muse, mutect2, varscan2
- DCLK1 | c.*2276G>A | 3'UTR (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- DERL1 | c.*2215T>A | 3'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- EEF2K | c.*281dup | 3'UTR (INS) | VAF 25/135 reads (19%) | catalogued as rs1042283093; called by mutect2, varscan2
- EFCAB1 | c.*860T>G | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- EFCAB14 | c.*3117T>C | 3'UTR (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- ESYT3 | c.*1241C>T | 3'UTR (SNP) | VAF 27/110 reads (25%) | catalogued as rs545352136; called by muse, mutect2, varscan2
- HYOU1 | c.*187G>A | 3'UTR (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- IGLV1-41 | n.89T>C | RNA (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- IL12A | c.-202C>G | 5'UTR (SNP) | VAF 44/182 reads (24%) | called by muse, mutect2, varscan2
- IMPDH2 | c.99-17A>T | Intron (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- KIAA1549L | c.*3397A>G | 3'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- LHX6 | chr9:122228300 C>T | 5'Flank (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- LYPLA1 | c.*1662C>T | 3'UTR (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- MOB3B | c.*2184del | 3'UTR (DEL) | VAF 4/38 reads (11%) | catalogued as rs1302031984; called by pindel, varscan2
- MYO3A | c.731+679G>C | Intron (SNP) | VAF 5/33 reads (15%) | catalogued as COSV56342729; called by muse, mutect2, varscan2
- NAP1L4 | c.1036-42C>G | Intron (SNP) | VAF 43/117 reads (37%) | called by muse, mutect2, varscan2
- NXN | c.820+40A>G | Intron (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | chr9:110171086 G>C | 3'Flank (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- PCDH1 | c.3319+1014G>C | Intron (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- PDPK1 | c.*5183T>A | 3'UTR (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- PHC3 | c.*984A>G | 3'UTR (SNP) | VAF 8/26 reads (31%) | catalogued as rs1302553869; called by muse, mutect2, varscan2
- RBM43 | c.*2773A>G | 3'UTR (SNP) | VAF 40/134 reads (30%) | called by muse, mutect2, varscan2
- RIMS2 | c.*1310T>C | 3'UTR (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- RIPOR1 | c.*243C>A | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- RPS23 | c.*2336A>G | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- RXFP1 | c.1346-223G>T | Intron (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- SLMAP | c.1336+3044C>A | Intron (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- TLL1 | c.*964dup | 3'UTR (INS) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- USP11 | c.2286+13C>T | Intron (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- VASP | c.873+33T>G | Intron (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- WAPL | c.*666A>T | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
